CPTAC case 11BR032 — Breast — Ductal and Lobular Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/c0cef5fc-0c80-4812-aece-97c351747f26

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Infiltrating lobular carcinoma, NOS: ICD-O-3 morphology code: 8520/3; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 49.5 years (18,067 days); AJCC pathologic stage: Stage IIA; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 314de592-f356-4801-8ace-278173: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 560627f2-6763-475a-8c1d-009ef9: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
